CCDI case PBCEUU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Meningiomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/d5f4372f-948f-49ae-8351-29a9f62391bc

Demographics
Sex at birth: male; Race: native hawaiian or other pacific islander.

Diagnoses (1)
1. Meningiomatosis, NOS: ICD-O-3 morphology code: 9530/1; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 11.0 years (4,017 days).

Biospecimens (3 samples)
- Sample 0DRO3H: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DRO3P: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DRO3U: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
